FM case AD8124 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/30cdd7c6-88db-41fd-a267-f78d812cd784

Female, 58.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the fallopian tube; metastasis biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
